Gene-level copy-number profile of tumor specimen TCGA-56-8504-01A from TCGA case TCGA-56-8504, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 74.5 years (27,210 days).
Specimen TCGA-56-8504-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.5ca28bad-23cb-4ea8-8ea5-09e10d3bf9f3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-56-8504-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ab768046-df5e-4a2a-8bf1-6f9cd0d8d76a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 371; copy number 2: 8,452; copy number 3: 25,256; copy number 4: 11,831; copy number 5: 4,988; copy number 6: 5,080; copy number 7: 2,173; copy number 8: 570; copy number 9: 1,064; copy number 10: 22; copy number 11: 5; copy number 12: 4; copy number 15: 1; copy number 18: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-56-8504-01A-11D-2391-01): tumor purity 0.35, ploidy 3.73, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,807 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:171,841,498–172,418,466, 1 gene, copy number 7 (within-gene range 4–7): DNM3.
- chr1:172,138,397–172,444,086, 7 genes, copy number 7 (within-gene range 4–7): DNM3OS, MIR214, MIR3120, MIR199A2, AL137157.1, RNU6-157P, PIGC.
- chr1:209,528,455–209,567,673, 2 genes, copy number 9 (within-gene range 4–9): AL023754.1, AL023754.2.
- chr2:142,131,178–169,115,680, 313 genes, copy number 7–10 (broad region; genes not listed).
- chr2:195,003,711–200,812,170, 79 genes, copy number 7–15 (within-gene range 6–15) (broad region; genes not listed).
- chr3:116,582,552–118,810,836, 16 genes, copy number 8 (within-gene range 6–8): RN7SL582P, BZW1P2, TUSC7, AC108713.1, MIR4447, AC069504.1, LINC00901, RNU5E-8P, PTMAP8, RNU6-1200P, AC092691.1, AC092691.2, LINC02024, AC092691.3, AC068633.1, AC068633.2.
- chr3:130,293,337–198,222,513, 1,171 genes, copy number 7–12 (broad region; genes not listed).
- chr4:77,216,416–77,216,878, 1 gene, copy number 11: AC008638.3.
- chr5:45,254,948–53,326,565, 45 genes, copy number 7 (within-gene range 5–7): HCN1, AC117529.2, AC117529.1, AC122694.1, EMB, AC112187.2, AC112187.1, AC112187.3, PARP8, AC022441.1, AC022441.3, AC022441.2, AC008808.2, LINC02106, AC008808.1, RNU6-480P, AC091834.1, RNU6-1296P, AC026798.1, AC010478.1, ISL1, HMGB1P47, AC091860.1, AC022433.1, AC091860.2, RNA5SP182, KATNBL1P4, AC091903.1, LINC02118, RPS17P11, MFSD4BP1, AC022126.1, PELO, ITGA1, AC022133.2, B3GNTL1P1, AC022133.1, AC025180.1, ITGA2, AC008966.3, AC008966.2, MOCS2, AC008966.1, AC026477.1, AC027329.1.
- chr7:78,392,626–78,487,028, 2 genes, copy number 9 (within-gene range 5–9): AC006043.1, AC007237.1.
- chr7:104,126,341–108,995,029, 79 genes, copy number 7 (broad region; genes not listed).
- chr8:5,072,645–5,072,869, 1 gene, copy number 7: AC019176.1.
- chr8:43,672,823–43,674,591, 2 genes, copy number 18: AC139365.2, AC139365.1.
- chr8:122,414,332–139,508,971, 233 genes, copy number 7–11 (broad region; genes not listed).
- chr9:32,384,603–36,124,455, 184 genes, copy number 7 (broad region; genes not listed).
- chr11:21,260,061–21,843,210, 4 genes, copy number 7: AC090857.2, AC099730.1, RNA5SP337, AC130307.1.
- chr11:66,040,765–71,452,868, 207 genes, copy number 7 (broad region; genes not listed).
- chr12:66,767–4,026,658, 98 genes, copy number 8–12 (broad region; genes not listed).
- chr12:26,120,030–31,327,058, 102 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr12:114,104,542–114,105,931, 1 gene, copy number 8: GLULP5.
- chr13:75,109,587–75,136,940, 2 genes, copy number 8: RNU6-38P, SSR1P2.
- chr14:70,044,215–106,875,071, 1,060 genes, copy number 9 (broad region; genes not listed).
- chr16:46,469,341–54,657,662, 196 genes, copy number 7–10 (broad region; genes not listed).
- chr16:54,847,316–54,854,991, 1 gene, copy number 7 (within-gene range 6–7): AC106742.1.

Autosomal genes at a single copy (total copy number 1): 363. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
